CGCI case HTMCP-02-25-01217 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0cb7003f-3467-4bf1-8583-918a9b19edd2

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Dead; Days to death: 3,180 days (8.7 years).

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 66.5 years (24,291 days); Year of diagnosis: 1996; Method of diagnosis: Other; AJCC staging edition: 4th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 3,179 days (8.7 years).
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 3,179 days (8.7 years); Disease response: Tumor Free.
- Follow-up contacts recording only the day: day -550, day 0.

Molecular and laboratory tests
- Test (IHC): Positive; Specialized molecular test: P40.

Other clinical attributes
- Day -550: Comorbidities: HIV/AIDS.
- Day -550: Risk factors: HIV/AIDS.
- Day 0: CD4 count: 650; Haart treatment indicator: Yes; HIV viral load: 1703.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-02-25-01217-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-25-01217-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-25-01217-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Squamous Cell Carcinoma, Not Otherwise Specified; Tumor status: Tumor free; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; Tobacco smoking history indicator: 1; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Lower lobe.
- History of disease: Year of HIV diagnosis: 1995; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes.
- Primary pathology: Lymph nodes examined: No; Method initial path diagnosis: Other method, specify:; Days from index date to tumor sample procurement: 20; Method initial path diagnosis other: bronchial brushing.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-25-01217-01A-01E-11090:
- % tumour top: 75
- % tumour bottom: 75

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-25-01217-11A-01E-11090:
- % tumour top: 0
- % tumour bottom: 0

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-25-01217-01A-01S-11090:
- % tumour top: 75
- % tumour bottom: 75
